Surgical pathology report (de-identified scan), TCGA case TCGA-FS-A4F5, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Essen, specimen TCGA-FS-A4F5-06A (Metastatic).

Patient: XXXX

Translation of pathology report

Sample

Gross Pathology

Cryofixed specimen with a weight of 89 mg.

Microscopic pathology

The H&E stained slide at hand shows an epitheloid malignant tumor with sparse amount of connective tissue. The tumor constitute approx. 95 percent of the tissue. The tumor cells show round to oval nuclei with granular chromatine.

There is a high nucleo/cytoplasmatic ratio. The mitotic count is xy mitoses per square millimetre. The tumor cells have a middle sized cytoplasm.

The tumor shows a sheet like growth pattern.

Lymphocytic infiltrates compound approx. 5 percent of the tissue cells.
The tumor harbours approx. 5 percent of necrotic tissue.

Diagnosis: Parts of a malignant tumor, consistent with a metastasis of a melanoma.

ICD-O-3
Melanoma, NOS 8720/3
Site: Subcutaneous tissue, NOS C49.9
(pms TSS)

JW
10/7/12

Source: NCI Genomic Data Commons file 3368e0ea-ddab-473f-8335-b74b315f24a8 (TCGA-FS-A4F5.4C3D0EB8-5A80-4D5D-B555-3A9F7CC31134.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).